Somatic mutation profile of tumor specimen ALCH-B368-TTP1-A (aliquot ALCH-B368-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B368, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 64.4 years (23,531 days).
Specimen ALCH-B368-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7788d4e3-d5bc-4bd9-8c4e-54025b5fc243.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B368-NB1-A (Blood Derived Normal), aliquot ALCH-B368-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c26736c2-4536-4e90-984c-460e56948d58

The open-access MAF lists 322 somatic variants for this specimen: 225 protein-altering or splice-affecting, 55 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 177, Silent 55, Nonsense Mutation 17, Intron 16, Frame Shift Del 11, 5'UTR 11, Splice Site 8, RNA 7, Splice Region 6, Frame Shift Ins 5, 5'Flank 5, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MMUT | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs772552898, CM050683, COSV99222325; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.278A>G p.H93R | Missense Mutation (SNP) | VAF 88/273 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs121909238, CM051214, COSV100910602, COSV64296545, COSV64296755; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLCO2A1 | c.1807C>T p.R603* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as rs776813259, CM1311291; ClinVar: pathogenic; called by muse, mutect2
- ACSM5 | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 34/201 reads (17%) | catalogued as rs780288053; called by muse, mutect2, varscan2
- ADGRG6 | c.1896G>A p.M632I | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as rs769911718; called by muse, mutect2
- AHNAK | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.116); catalogued as rs777135489; called by muse, mutect2, varscan2
- AMER1 | c.3038C>T p.P1013L | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs765991551; called by muse, mutect2, varscan2
- ANTXRL | c.181C>A p.H61N | Missense Mutation (SNP) | VAF 64/184 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0.242); catalogued as rs1554955540; called by muse, varscan2
- APOBEC3F | c.525C>A p.D175E | Missense Mutation (SNP) | VAF 36/245 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as rs527685670; called by muse, mutect2, varscan2
- ATP9B | c.310A>G p.I104V | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs777060597; called by muse, mutect2, varscan2
- BICC1 | c.2491G>T p.A831S | Missense Mutation (SNP) | VAF 63/357 reads (18%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV99570044; called by muse, mutect2, varscan2
- BRWD3 | c.5132G>A p.R1711K | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.05); catalogued as COSV64749162; called by muse, mutect2, varscan2
- BSN | c.9977G>A p.R3326K | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.056); catalogued as rs376386796; called by muse, mutect2, varscan2
- CACNA2D1 | c.2611-1G>T p.X871_splice (on ENST00000356253 / NM_001366867.1; = p.X859_splice on NM_000722.4) | Splice Site (SNP) | VAF 16/90 reads (18%) | catalogued as COSV100666588; called by muse, mutect2
- CDK15 | c.592C>G p.P198A (on ENST00000652192 / NM_001366386.2; = p.P147A on NM_139158.2) | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as rs1179844780; called by muse, mutect2
- CHST7 | c.20G>C p.R7P | Missense Mutation (SNP) | VAF 46/287 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as rs1247550163, COSV99333011; called by muse, mutect2, varscan2
- CNGA2 | c.589+1G>A p.X197_splice | Splice Site (SNP) | VAF 20/144 reads (14%) | catalogued as COSV61705129; called by muse, mutect2, varscan2
- CSH2 | c.10+6C>T | Splice Region (SNP) | VAF 57/358 reads (16%) | catalogued as rs780794922; called by muse, mutect2
- CUL9 | c.2932G>A p.G978R | Missense Mutation (SNP) | VAF 65/380 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.027); catalogued as rs1023703620; called by muse, mutect2, varscan2
- DENND2A | c.2207C>G p.S736C | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as rs753667814; called by muse, mutect2, varscan2
- DMD | c.3921T>C p.D1307= | Splice Region (SNP) | VAF 39/247 reads (16%) | catalogued as rs753416782; called by muse, varscan2
- DNAAF3 | c.214C>T p.R72C (on ENST00000524407 / NM_001256715.2; = p.R119C on NM_178837.4) | Missense Mutation (SNP) | VAF 30/422 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs750438145; called by muse, mutect2
- DSPP | c.1463G>T p.R488L | Missense Mutation (SNP) | VAF 96/579 reads (17%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.205); catalogued as COSV99217130; called by muse, mutect2, varscan2
- EFCAB5 | c.3766C>T p.R1256C | Missense Mutation (SNP) | VAF 56/366 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs190450097, COSV57926515; called by muse, mutect2, varscan2
- ENGASE | c.364A>T p.R122W | Missense Mutation (SNP) | VAF 98/389 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1400016278; called by muse, mutect2, varscan2
- ENGASE | c.365G>T p.R122M | Missense Mutation (SNP) | VAF 97/386 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs1445075832; called by muse, mutect2, varscan2
- ERI1 | c.699G>T p.W233C | Missense Mutation (SNP) | VAF 81/205 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1171572202, COSV99141425; called by muse, mutect2, varscan2
- FREM2 | c.5984G>T p.G1995V | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV99751534; called by muse, mutect2, varscan2
- HECTD4 | c.2479G>A p.D827N | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as rs868718215; called by muse, mutect2, varscan2
- HIVEP3 | c.5248G>T p.G1750C | Missense Mutation (SNP) | VAF 56/240 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56025664; called by muse, mutect2, varscan2
- IBSP | c.847G>T p.G283W | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56894557; called by muse, mutect2, varscan2
- IMPG1 | c.25A>G p.I9V | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1382214932; called by muse, mutect2, varscan2
- KCNG4 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as rs772484443, COSV57583317; called by muse, mutect2, varscan2
- KIAA1549L | c.1135A>G p.M379V (on ENST00000321505; = p.M676V on NM_012194.3) | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1349458688; called by muse, mutect2, varscan2
- KIF20B | c.1711G>C p.E571Q | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV99590593; called by muse, mutect2, varscan2
- L3MBTL1 | c.1498C>A p.L500I (on ENST00000418998 / NM_001377303.1; = p.L410I on NM_015478.7) | Missense Mutation (SNP) | VAF 55/158 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64229120; called by muse, mutect2, varscan2
- LGR4 | c.2299dup p.S767Ffs*43 | Frame Shift Ins (INS) | VAF 16/92 reads (17%) | catalogued as rs1229958149; called by mutect2, varscan2
- LINGO2 | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58060155, COSV58063806; called by muse, mutect2, varscan2
- LRIG3 | c.2948G>A p.R983Q | Missense Mutation (SNP) | VAF 32/229 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs753738730; called by muse, mutect2, varscan2
- LRRC4B | c.1388G>A p.G463D | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.931); catalogued as rs749356572; called by muse, mutect2, varscan2
- LRRC4C | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 63/204 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV53433104; called by muse, mutect2, varscan2
- LTA | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 43/322 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs1385681949, COSV101403219; called by muse, mutect2, varscan2
- MAGEB1 | c.578G>A p.W193* | Nonsense Mutation (SNP) | VAF 24/179 reads (13%) | catalogued as COSV100974984; called by muse, mutect2, varscan2
- MAGEB6 | c.1039G>T p.V347L | Missense Mutation (SNP) | VAF 37/265 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as rs954342921, COSV99081185; called by muse, mutect2, varscan2
- MAP4K3 | c.1957G>T p.D653Y | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55715457; called by muse, mutect2, varscan2
- MTMR1 | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs990248555, COSV64892695; called by muse, mutect2, varscan2
- MUC2 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 86/290 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs541501827; called by muse, mutect2, varscan2
- MXRA5 | c.1651G>A p.G551S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54238399; called by muse, mutect2, varscan2
- MYO5C | c.2254C>T p.R752* | Nonsense Mutation (SNP) | VAF 31/146 reads (21%) | catalogued as rs764090555, COSV55903246; called by muse, mutect2, varscan2
- NOTCH2 | c.4503G>C p.K1501N | Missense Mutation (SNP) | VAF 122/480 reads (25%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.505); catalogued as COSV56709662; called by muse, mutect2, varscan2
- OBSCN | c.9976A>G p.M3326V | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769644250; called by muse, mutect2, varscan2
- ODF3 | c.318C>G p.Y106* | Nonsense Mutation (SNP) | VAF 34/213 reads (16%) | catalogued as COSV57293320; called by muse, mutect2, varscan2
- OR11H2 | c.556G>C p.G186R (on ENST00000556246; = p.G197R on NM_001197287.1) | Missense Mutation (SNP) | VAF 67/1240 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV73703671; called by muse, mutect2
- OR4K2 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 22/296 reads (7%) | catalogued as rs1160415899; called by muse, mutect2
- OTOGL | c.3902C>T p.S1301L (on ENST00000547103; = p.S1292L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/310 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV101509530; called by muse, mutect2, varscan2
- PCDHGA8 | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 44/292 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as rs747606142; called by muse, mutect2, varscan2
- PDZD4 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs782383096, COSV51246281; called by muse, mutect2, varscan2
- PHEX | c.1573G>A p.V525I | Missense Mutation (SNP) | VAF 21/236 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as rs879138132; called by muse, mutect2
- PHLPP1 | c.3604C>T p.R1202C | Missense Mutation (SNP) | VAF 79/179 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs760057011, COSV53027309; called by muse, mutect2, varscan2
- POU6F2 | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs747165081; called by muse, mutect2, varscan2
- PPFIA2 | c.2875C>A p.Q959K | Missense Mutation (SNP) | VAF 69/250 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV61024597; called by muse, mutect2, varscan2
- PRDM9 | c.334C>G p.Q112E | Missense Mutation (SNP) | VAF 314/658 reads (48%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.036); catalogued as rs1487956793; called by muse, varscan2
- RDH12 | c.904C>A p.R302S | Missense Mutation (SNP) | VAF 156/437 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); catalogued as COSV50821372; called by muse, mutect2, varscan2
- RGPD3 | c.2863C>T p.R955W | Missense Mutation (SNP) | VAF 115/810 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs567422835; called by muse, mutect2, varscan2
- RIT2 | c.192C>A p.D64E | Missense Mutation (SNP) | VAF 76/244 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1280601502; called by muse, mutect2, varscan2
- RNF217 | c.92C>G p.P31R | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.01); catalogued as rs1176626480; called by mutect2, varscan2
- SHOX2 | c.557T>C p.V186A (on ENST00000441443 / NM_006884.3; = p.V210A on NM_003030.4) | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV67463426, COSV67463728, COSV67464226; called by muse, mutect2, varscan2
- SLC5A2 | c.198+6A>T | Splice Region (SNP) | VAF 55/309 reads (18%) | catalogued as rs747772485; called by muse, mutect2, varscan2
- SRSF6 | c.866T>C p.I289T | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs779384024; called by muse, mutect2, varscan2
- STOML1 | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs768236910; called by muse, mutect2
- TACC2 | c.5738C>T p.S1913L | Missense Mutation (SNP) | VAF 72/162 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs377123555; called by muse, mutect2, varscan2
- TAZ | c.521G>C p.W174S | Missense Mutation (SNP) | VAF 33/335 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54797267; called by muse, mutect2, varscan2
- TCEAL3 | c.436G>T p.V146L | Missense Mutation (SNP) | VAF 30/542 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV54581627; called by muse, mutect2
- TIMP3 | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 98/344 reads (28%) | catalogued as COSV99831273; called by muse, mutect2
- TMEM245 | c.2396C>T p.S799L | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV65823640; called by mutect2, varscan2
- TP53 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 54/120 reads (45%) | catalogued as COSV52771366, COSV52826932, COSV52883452; called by muse, mutect2, varscan2
- TRHDE | c.1313T>C p.I438T | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs1261206616; called by muse, mutect2, varscan2
- TRIM43 | c.508-2A>C p.X170_splice | Splice Site (SNP) | VAF 86/365 reads (24%) | catalogued as rs1306743417; called by muse, mutect2, varscan2
- VCAN | c.2761G>T p.E921* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV54115035; called by mutect2, varscan2
- VIT | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as rs746041170, COSV64896475; called by muse, mutect2, varscan2
- WAS | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as CD096363; called by muse, mutect2, varscan2
- ZFP62 | c.1469C>G p.S490C (on ENST00000502412 / NM_001377944.1; = p.S457C on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1208475216; called by muse, mutect2, varscan2
- ZNF385B | c.1420A>G p.I474V | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.044); catalogued as rs1413597404; called by muse, mutect2, varscan2
- ABCB1 | c.3334C>A p.H1112N | Missense Mutation (SNP) | VAF 48/294 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- ACSS1 | c.1192G>T p.G398C | Missense Mutation (SNP) | VAF 78/307 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ACVR1 | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 32/232 reads (14%) | called by muse, mutect2, varscan2
- ADAD1 | c.140C>A p.S47Y | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- ADGRF4 | c.1441C>A p.H481N | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALPG | c.1190C>A p.A397D | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- ANKEF1 | c.1058G>A p.S353N | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2
- ANO6 | c.2521A>T p.M841L | Missense Mutation (SNP) | VAF 96/504 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- AP4E1 | c.1811A>G p.K604R | Missense Mutation (SNP) | VAF 44/246 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AQR | c.2641C>T p.H881Y | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- ARID1A | c.1113dup p.Q372Afs*28 | Frame Shift Ins (INS) | VAF 11/75 reads (15%) | called by mutect2, pindel, varscan2
- ASPH | c.926T>C p.V309A | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.026); called by muse, mutect2
- ATP5MC3 | c.174G>C p.R58S | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- BBS7 | c.1283G>C p.S428T | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- BCL6 | c.902A>T p.K301I | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BHLHE23 | c.106G>A p.A36T (on ENST00000370346; = p.A52T on NM_080606.4) | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRWD3 | c.2181G>A p.M727I | Missense Mutation (SNP) | VAF 11/238 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.085); called by muse, mutect2
- BTBD8 | c.5073A>T p.Q1691H (on ENST00000636805 / NM_001376131.1; = p.Q1178H on NM_015237.4) | Missense Mutation (SNP) | VAF 65/279 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- BTLA | c.65A>G p.Y22C | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- CACHD1 | c.1921T>C p.C641R | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- CALCA | c.412del p.Q138Rfs*22 | Frame Shift Del (DEL) | VAF 95/417 reads (23%) | called by mutect2, pindel, varscan2
- CARMIL3 | c.3302G>C p.G1101A | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.601); called by mutect2, varscan2
- CCDC158 | c.923C>G p.A308G | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCDC18 | c.4272T>A p.S1424R | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- CCL15 | c.152_154del p.A51del | In Frame Del (DEL) | VAF 98/414 reads (24%) | called by pindel, varscan2
- CCNB3 | c.1371G>T p.L457F | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CD109 | c.778G>T p.V260L | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- CD1E | c.955C>A p.L319M | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CDT1 | c.936C>T p.A312= | Splice Region (SNP) | VAF 9/238 reads (4%) | called by muse, mutect2
- CGN | c.1568A>T p.Q523L | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- COL6A5 | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CYSLTR1 | c.606del p.F202Lfs*4 | Frame Shift Del (DEL) | VAF 9/92 reads (10%) | called by mutect2, pindel
- DACH2 | c.311del p.G104Efs*10 | Frame Shift Del (DEL) | VAF 38/240 reads (16%) | called by mutect2, pindel, varscan2
- DCAF8L2 | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 36/243 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- DCTN1 | c.2024C>T p.S675F | Missense Mutation (SNP) | VAF 129/517 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- DNHD1 | c.11103A>T p.E3701D | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- DROSHA | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 62/327 reads (19%) | called by muse, mutect2, varscan2
- ELMOD1 | c.222del p.D75Tfs*7 | Frame Shift Del (DEL) | VAF 23/138 reads (17%) | called by mutect2, pindel, varscan2
- FBXW12 | c.195G>A p.W65* | Nonsense Mutation (SNP) | VAF 26/81 reads (32%) | called by muse, mutect2, varscan2
- FLNA | c.6366C>A p.D2122E (on ENST00000369850 / NM_001110556.2; = p.D2114E on NM_001456.3) | Missense Mutation (SNP) | VAF 67/267 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- FREM3 | c.1465G>T p.G489W | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- FRMPD3 | c.3476G>T p.R1159L | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- GFRAL | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 73/294 reads (25%) | called by muse, mutect2, varscan2
- GK | c.1391G>T p.G464V (on ENST00000427190 / NM_001205019.2; = p.G458V on NM_000167.6) | Missense Mutation (SNP) | VAF 84/501 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GUCY2C | c.1145T>C p.L382P | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, varscan2
- HCFC1 | c.1967G>T p.G656V | Missense Mutation (SNP) | VAF 58/281 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- HCN3 | c.2230C>T p.L744F | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- HGF | c.284A>T p.Q95L | Missense Mutation (SNP) | VAF 51/290 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- HINT3 | c.244A>T p.T82S | Missense Mutation (SNP) | VAF 19/206 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- HKDC1 | c.1766G>T p.G589V | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- HSF5 | c.1071G>T p.W357C | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGA8 | c.2637+2T>G p.X879_splice | Splice Site (SNP) | VAF 18/61 reads (30%) | called by muse, mutect2, varscan2
- ITIH6 | c.2521G>T p.G841W | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- JPH2 | c.1635C>G p.I545M | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- KIAA0100 | c.4617_4618dup p.I1540Kfs*9 | Frame Shift Ins (INS) | VAF 10/86 reads (12%) | called by mutect2, varscan2
- KLHL36 | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 28/113 reads (25%) | called by muse, mutect2, varscan2
- KLK4 | c.627dup p.P210Afs*36 | Frame Shift Ins (INS) | VAF 57/544 reads (10%) | called by mutect2, pindel, varscan2
- LAMA4 | c.1406C>G p.T469S (on ENST00000230538 / NM_001105206.3; = p.T462S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/354 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMP2 | c.915G>T p.L305F | Missense Mutation (SNP) | VAF 62/388 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.029); called by muse, mutect2
- LEPR | c.1401T>C p.H467= | Splice Region (SNP) | VAF 99/560 reads (18%) | called by muse, mutect2, varscan2
- LIG4 | c.970C>G p.Q324E | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRRC43 | c.1009A>C p.T337P | Missense Mutation (SNP) | VAF 46/270 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- LRRIQ1 | c.2067C>A p.N689K | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRK2 | c.1750G>T p.G584C | Missense Mutation (SNP) | VAF 42/301 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LTA | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 44/326 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- MAGEH1 | c.160G>C p.D54H | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- MAGEH1 | c.161A>T p.D54V | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MCCC1 | c.1655A>C p.N552T | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.011); called by muse, mutect2
- ME2 | c.907T>G p.S303A | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MEGF10 | c.1637A>T p.H546L | Missense Mutation (SNP) | VAF 78/252 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- MEIS1 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 41/361 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MIA2 | c.1909C>G p.P637A | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- MN1 | c.2586G>T p.Q862H | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MPP5 | c.840T>G p.I280M | Missense Mutation (SNP) | VAF 43/311 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MSL3 | c.720G>A p.M240I (on ENST00000312196 / NM_078629.4; = p.M74I on NM_006800.4) | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.025); called by muse, mutect2
- MYB | c.1908del p.T637Rfs*20 | Frame Shift Del (DEL) | VAF 60/226 reads (27%) | called by mutect2, pindel, varscan2
- MYO5C | c.4799G>A p.C1600Y | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- NAV3 | c.5887-1G>A p.X1963_splice (on ENST00000397909 / NM_001024383.2; = p.X1941_splice on NM_014903.6) | Splice Site (SNP) | VAF 15/84 reads (18%) | called by muse, mutect2
- NAV3 | c.6502C>G p.L2168V (on ENST00000397909 / NM_001024383.2; = p.L2146V on NM_014903.6) | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- NEIL1 | c.952dup p.S318Kfs*16 | Frame Shift Ins (INS) | VAF 22/111 reads (20%) | called by mutect2, pindel, varscan2
- NELL1 | c.82C>A p.L28I | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- NLGN3 | c.2362G>T p.A788S (on ENST00000358741 / NM_181303.2; = p.A768S on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/377 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NLRP12 | c.2408T>A p.M803K | Missense Mutation (SNP) | VAF 96/367 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- NLRP3 | c.1444T>G p.F482V | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NLRP5 | c.35C>A p.A12D | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- NUP42 | c.826T>A p.S276T | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- OR1D2 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- OR52B2 | c.513C>A p.C171* | Nonsense Mutation (SNP) | VAF 54/195 reads (28%) | called by muse, mutect2, varscan2
- OR5D14 | c.874T>C p.Y292H | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- PCDH15 | c.4907C>T p.P1636L | Missense Mutation (SNP) | VAF 29/231 reads (13%) | SIFT tolerated, low confidence (0.15); called by muse, mutect2, varscan2
- PDPR | c.2404A>G p.S802G | Missense Mutation (SNP) | VAF 38/263 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- PEX12 | c.114G>C p.Q38H | Missense Mutation (SNP) | VAF 20/682 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.024); called by muse, mutect2
- PIK3C2A | c.1918C>G p.P640A | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- PLEKHA6 | c.3128G>T p.S1043I | Missense Mutation (SNP) | VAF 55/358 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PM20D2 | c.161A>G p.E54G | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- PMP2 | c.23C>A p.T8N | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- PPP1R10 | c.157A>G p.I53V | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PPP1R3F | c.587C>G p.A196G | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- PRDM2 | c.2143G>T p.G715C | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PRR12 | c.1552G>T p.G518* (on ENST00000615927; = p.G1339* on NM_020719.3) | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- RAPGEF4 | c.2872G>C p.A958P | Missense Mutation (SNP) | VAF 40/264 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASGRP4 | c.177T>A p.D59E | Missense Mutation (SNP) | VAF 117/423 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RECK | c.2843G>T p.R948M | Missense Mutation (SNP) | VAF 41/236 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RIPPLY3 | c.45_48del p.G16Vfs*35 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- RNF38 | c.79A>G p.R27G | Missense Mutation (SNP) | VAF 60/226 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RPIA | c.319A>G p.T107A | Missense Mutation (SNP) | VAF 155/614 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- RPS4X | c.322C>A p.R108S | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- RTRAF | c.532-2A>G p.X178_splice | Splice Site (SNP) | VAF 23/124 reads (19%) | called by muse, mutect2, varscan2
- SAA2 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 59/248 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- SBK2 | c.979C>A p.R327S | Missense Mutation (SNP) | VAF 57/255 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SHROOM2 | c.979G>C p.A327P | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- SKOR1 | c.2803G>T p.E935* | Nonsense Mutation (SNP) | VAF 48/264 reads (18%) | called by muse, mutect2, varscan2
- SLC10A4 | c.1250_1257del p.T417Rfs*41 | Frame Shift Del (DEL) | VAF 11/72 reads (15%) | called by mutect2, pindel, varscan2
- SLC12A7 | c.1187C>A p.P396H | Missense Mutation (SNP) | VAF 32/330 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2
- SLC35D3 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 37/253 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLITRK3 | c.1526T>C p.L509P | Missense Mutation (SNP) | VAF 83/407 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- SNRNP200 | c.856del p.A286Qfs*8 | Frame Shift Del (DEL) | VAF 78/374 reads (21%) | called by mutect2, pindel, varscan2
- SPDEF | c.364del p.V122Cfs*94 | Frame Shift Del (DEL) | VAF 55/186 reads (30%) | called by mutect2, pindel, varscan2
- STIMATE | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 72/173 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- STRIP2 | c.584A>G p.D195G | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SUPT20HL1 | c.1993G>T p.A665S | Missense Mutation (SNP) | VAF 60/335 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SYT1 | c.359A>G p.K120R | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TAT | c.283del p.Q95Rfs*3 | Frame Shift Del (DEL) | VAF 71/393 reads (18%) | called by mutect2, pindel, varscan2
- TBC1D25 | c.1466C>A p.A489D | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.02); called by muse, mutect2
- TCEAL3 | c.434A>G p.D145G | Missense Mutation (SNP) | VAF 30/536 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- THSD7A | c.3883del p.W1295Gfs*14 | Frame Shift Del (DEL) | VAF 24/177 reads (14%) | called by mutect2, pindel, varscan2
- TIMM8A | c.211A>T p.I71F | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- TMEM63C | c.493G>T p.D165Y | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TNRC18 | c.2384C>T p.P795L | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRAPPC11 | c.2964-2A>T p.X988_splice | Splice Site (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- UBQLN3 | c.1535A>G p.Q512R | Missense Mutation (SNP) | VAF 21/214 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); called by muse, mutect2
- UGT2A2 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- UNC79 | c.3873T>A p.D1291E (on ENST00000393151 / NM_001346218.2; = p.D1114E on NM_020818.5) | Missense Mutation (SNP) | VAF 46/333 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- URB2 | c.126+1_126+5del p.X42_splice | Splice Site (DEL) | VAF 9/97 reads (9%) | called by mutect2, pindel
- USH2A | c.14932G>T p.D4978Y | Missense Mutation (SNP) | VAF 45/253 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- USH2A | c.12295A>C p.T4099P | Missense Mutation (SNP) | VAF 70/519 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- USP24 | c.2783T>A p.L928Q | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- USP45 | c.1531G>C p.E511Q | Missense Mutation (SNP) | VAF 27/224 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ZFAND5 | c.492A>G p.T164= | Splice Region (SNP) | VAF 20/154 reads (13%) | called by muse, mutect2, varscan2
- ZFC3H1 | c.2942A>G p.Q981R | Missense Mutation (SNP) | VAF 52/205 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ZMYM3 | c.848G>T p.R283L | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- ZNF831 | c.1447C>A p.L483I | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.314); called by muse, mutect2
- AKR7L | c.579C>T p.F193= | Silent (SNP) | VAF 90/379 reads (24%) | called by muse, mutect2, varscan2
- ARHGAP21 | c.3351A>G p.P1117= | Silent (SNP) | VAF 44/141 reads (31%) | catalogued as rs745676132; called by muse, mutect2, varscan2
- ARHGAP31 | c.3753T>A p.S1251= | Silent (SNP) | VAF 58/235 reads (25%) | called by muse, mutect2, varscan2
- ARL6IP4 | c.228G>A p.E76= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs756298215; called by muse, mutect2, varscan2
- ARMCX4 | c.489C>A p.A163= (on ENST00000433011; = p.A59= on NM_001256155.2) | Silent (SNP) | VAF 44/364 reads (12%) | called by muse, mutect2, varscan2
- ATP11C | c.1098A>C p.V366= | Silent (SNP) | VAF 27/214 reads (13%) | called by muse, mutect2, varscan2
- B4GALNT4 | c.2115C>T p.C705= | Silent (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2
- C4orf54 | c.351C>G p.L117= | Silent (SNP) | VAF 27/100 reads (27%) | called by muse, mutect2, varscan2
- CARD6 | c.1812A>T p.P604= | Silent (SNP) | VAF 24/296 reads (8%) | called by muse, mutect2
- CNTNAP2 | c.1920G>T p.V640= | Silent (SNP) | VAF 52/326 reads (16%) | called by muse, mutect2, varscan2
- CTDP1 | c.2292G>A p.K764= | Silent (SNP) | VAF 53/372 reads (14%) | called by muse, mutect2, varscan2
- DEPTOR | c.1179G>A p.L393= | Silent (SNP) | VAF 32/344 reads (9%) | catalogued as COSV99638180; called by muse, mutect2
- DIAPH2 | c.582G>T p.P194= | Silent (SNP) | VAF 60/268 reads (22%) | catalogued as rs201709490; called by muse, mutect2, varscan2
- DNAH5 | c.951G>T p.A317= | Silent (SNP) | VAF 95/666 reads (14%) | catalogued as COSV99447175; called by muse, mutect2, varscan2
- FAM90A14P | c.768C>A p.P256= | Silent (SNP) | VAF 77/669 reads (12%) | called by muse, mutect2, varscan2
- HFM1 | c.3594G>A p.Q1198= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs776993117, COSV99645079; called by muse, mutect2, varscan2
- IDS | c.27C>G p.G9= | Silent (SNP) | VAF 26/65 reads (40%) | called by muse, mutect2, varscan2
- ITSN2 | c.192T>A p.A64= | Silent (SNP) | VAF 20/62 reads (32%) | called by mutect2, varscan2
- LAMA3 | c.2562A>G p.G854= | Silent (SNP) | VAF 124/443 reads (28%) | called by muse, mutect2, varscan2
- LIMK1 | c.1314G>T p.V438= | Silent (SNP) | VAF 36/189 reads (19%) | called by muse, mutect2, varscan2
- LOXHD1 | c.1021C>A p.R341= | Silent (SNP) | VAF 53/355 reads (15%) | catalogued as rs931911802; called by muse, mutect2, varscan2
- LYSMD3 | c.372A>G p.P124= | Silent (SNP) | VAF 79/249 reads (32%) | called by muse, mutect2, varscan2
- MRRF | c.27C>T p.R9= | Silent (SNP) | VAF 10/252 reads (4%) | called by muse, mutect2
- MUC17 | c.6351T>A p.P2117= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs371476183; called by muse, mutect2, varscan2
- MUC17 | c.6666C>T p.F2222= | Silent (SNP) | VAF 33/218 reads (15%) | called by muse, mutect2, varscan2
- MUC2 | c.186C>A p.P62= | Silent (SNP) | VAF 18/63 reads (29%) | called by muse, mutect2, varscan2
- MYT1L | c.1071C>T p.I357= | Silent (SNP) | VAF 109/368 reads (30%) | catalogued as rs1322793511; called by muse, mutect2, varscan2
- NBPF6 | c.1597C>T p.L533= | Silent (SNP) | VAF 102/292 reads (35%) | called by muse, mutect2, varscan2
- NCAPD3 | c.1020C>T p.A340= | Silent (SNP) | VAF 31/123 reads (25%) | called by muse, mutect2, varscan2
- OGT | c.2142C>T p.H714= | Silent (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2, varscan2
- OR5B17 | c.144G>T p.L48= | Silent (SNP) | VAF 59/246 reads (24%) | catalogued as COSV62160078; called by muse, mutect2, varscan2
- OR8I2 | c.456C>A p.G152= | Silent (SNP) | VAF 79/250 reads (32%) | called by muse, mutect2, varscan2
- PCDHB4 | c.1818C>G p.L606= | Silent (SNP) | VAF 64/448 reads (14%) | catalogued as COSV52027979; called by muse, mutect2, varscan2
- RTTN | c.957A>C p.T319= | Silent (SNP) | VAF 31/201 reads (15%) | called by muse, mutect2, varscan2
- RYR3 | c.14568C>A p.A4856= (on ENST00000389232; = p.A4857= on NM_001036.6) | Silent (SNP) | VAF 17/190 reads (9%) | catalogued as COSV100145761; called by muse, mutect2
- SBSPON | c.343C>T p.L115= | Silent (SNP) | VAF 8/97 reads (8%) | catalogued as rs375795680; called by muse, mutect2
- SERPINC1 | c.777A>T p.S259= | Silent (SNP) | VAF 49/211 reads (23%) | called by muse, mutect2, varscan2
- SMIM20 | c.57T>C p.S19= | Silent (SNP) | VAF 29/145 reads (20%) | catalogued as rs1560385004; called by muse, mutect2, varscan2
- SPATA31A6 | c.3330G>A p.R1110= | Silent (SNP) | VAF 201/861 reads (23%) | catalogued as rs748988944; called by muse, mutect2, varscan2
- STOML1 | c.696G>T p.G232= | Silent (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2
- TG | c.4899A>T p.T1633= | Silent (SNP) | VAF 50/426 reads (12%) | called by muse, mutect2, varscan2
- TICRR | c.90C>T p.L30= | Silent (SNP) | VAF 21/140 reads (15%) | called by muse, mutect2, varscan2
- TIMP1 | c.276C>A p.V92= | Silent (SNP) | VAF 20/69 reads (29%) | called by muse, mutect2, varscan2
- TNIP3 | c.231G>A p.T77= | Silent (SNP) | VAF 63/285 reads (22%) | catalogued as rs757586748, COSV50247852, COSV50248802; called by muse, mutect2, varscan2
- TRHDE | c.2823G>A p.R941= | Silent (SNP) | VAF 54/320 reads (17%) | called by muse, varscan2
- TWSG1 | c.204C>T p.D68= | Silent (SNP) | VAF 27/259 reads (10%) | catalogued as rs145134563; called by muse, mutect2, varscan2
- TYR | c.744A>G p.T248= | Silent (SNP) | VAF 16/68 reads (24%) | called by muse, mutect2, varscan2
- UGT2B10 | c.1518C>T p.I506= | Silent (SNP) | VAF 45/253 reads (18%) | catalogued as COSV55323562; called by muse, mutect2, varscan2
- ULK1 | c.2205G>T p.G735= | Silent (SNP) | VAF 20/58 reads (34%) | called by muse, mutect2, varscan2
- VPS13A | c.4395C>G p.V1465= | Silent (SNP) | VAF 27/212 reads (13%) | called by muse, mutect2, varscan2
- ZBED1 | c.1071G>T p.T357= | Silent (SNP) | VAF 47/276 reads (17%) | called by muse, mutect2, varscan2
- ZFYVE28 | c.1746G>T p.R582= | Silent (SNP) | VAF 22/125 reads (18%) | called by muse, mutect2, varscan2
- ZKSCAN1 | c.1401G>A p.G467= | Silent (SNP) | VAF 26/145 reads (18%) | catalogued as rs1359945980; called by muse, mutect2, varscan2
- ZNF462 | c.6864G>T p.R2288= | Silent (SNP) | VAF 49/121 reads (40%) | called by muse, mutect2, varscan2
- ZNF831 | c.1446C>A p.P482= | Silent (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2
- AL132655.6 | chr20:58840272 G>T | 5'Flank (SNP) | VAF 108/359 reads (30%) | called by muse, mutect2, varscan2
- AL590617.2 | n.1664G>T | RNA (SNP) | VAF 32/123 reads (26%) | called by muse, mutect2, varscan2
- ANK2 | c.-41C>A | 5'UTR (SNP) | VAF 25/163 reads (15%) | called by muse, mutect2, varscan2
- ARHGAP23P1 | chr16:33938357 G>T | 5'Flank (SNP) | VAF 6/50 reads (12%) | called by mutect2, varscan2
- C5orf17 | n.206T>A | RNA (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- CALR3 | c.*25A>C | 3'UTR (SNP) | VAF 14/151 reads (9%) | called by muse, mutect2, varscan2
- CCDC102B | c.1263+189C>A | Intron (SNP) | VAF 30/194 reads (15%) | catalogued as COSV100103810; called by muse, mutect2, varscan2
- COPG1 | c.-2C>T | 5'UTR (SNP) | VAF 15/142 reads (11%) | catalogued as rs1401516966; called by muse, mutect2, varscan2
- DMPK | c.161-457A>G | Intron (SNP) | VAF 5/35 reads (14%) | catalogued as rs1472441950; called by muse, mutect2
- ELK1 | chrX:47650576 C>A | 5'Flank (SNP) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- EMX2 | c.-33T>A | 5'UTR (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- FAM161A | c.184-4588C>T | Intron (SNP) | VAF 24/109 reads (22%) | catalogued as rs896226009; called by muse, mutect2, varscan2
- FNIP2 | c.-18A>G | 5'UTR (SNP) | VAF 22/113 reads (19%) | called by muse, mutect2, varscan2
- GATD1 | c.545-87G>A | Intron (SNP) | VAF 47/130 reads (36%) | called by muse, mutect2, varscan2
- GLDC | c.-49G>C | 5'UTR (SNP) | VAF 6/11 reads (55%) | called by muse, mutect2, varscan2
- GOLGA8IP | chr15:22617765 G>T | 5'Flank (SNP) | VAF 20/72 reads (28%) | called by mutect2, varscan2
- HEG1 | c.1589-871C>T | Intron (SNP) | VAF 58/185 reads (31%) | called by muse, mutect2, varscan2
- HERC2P3 | n.349T>A | RNA (SNP) | VAF 22/310 reads (7%) | called by muse, mutect2
- HUWE1 | c.8206+109G>T | Intron (SNP) | VAF 14/75 reads (19%) | called by muse, mutect2, varscan2
- IRF1 | c.414+24G>A | Intron (SNP) | VAF 59/159 reads (37%) | called by muse, mutect2, varscan2
- KRBOX4 | c.253+54G>C | Intron (SNP) | VAF 55/332 reads (17%) | called by muse, mutect2, varscan2
- KRT17P1 | n.514A>T | RNA (SNP) | VAF 53/458 reads (12%) | called by muse, mutect2, varscan2
- KRT5 | c.-47C>G | 5'UTR (SNP) | VAF 29/249 reads (12%) | catalogued as COSV99357825; called by muse, mutect2, varscan2
- LINC02694 | n.351C>A | RNA (SNP) | VAF 21/114 reads (18%) | called by muse, mutect2, varscan2
- MAP9 | c.708+17A>T | Intron (SNP) | VAF 22/149 reads (15%) | called by muse, varscan2
- NOL4L-DT | n.352G>T | RNA (SNP) | VAF 84/266 reads (32%) | called by muse, mutect2, varscan2
- PAX8 | c.-86G>T | 5'UTR (SNP) | VAF 26/137 reads (19%) | called by muse, mutect2, varscan2
- PIGQ | c.821+44C>G | Intron (SNP) | VAF 30/199 reads (15%) | called by muse, mutect2, varscan2
- PIM1 | c.608-346C>G | Intron (SNP) | VAF 64/520 reads (12%) | called by muse, mutect2, varscan2
- PPP3CA | c.259+24737G>C | Intron (SNP) | VAF 27/188 reads (14%) | called by muse, mutect2, varscan2
- PTGER3 | c.*24-12955C>T | Intron (SNP) | VAF 27/120 reads (23%) | called by muse, mutect2, varscan2
- RSPO4 | c.-36C>T | 5'UTR (SNP) | VAF 29/140 reads (21%) | catalogued as rs768594197; called by muse, mutect2, varscan2
- SLC13A4 | chr7:135728944 G>T | 5'Flank (SNP) | VAF 16/98 reads (16%) | called by muse, mutect2, varscan2
- SLC25A14 | c.594+360G>T | Intron (SNP) | VAF 58/265 reads (22%) | called by muse, mutect2, varscan2
- SLC26A5 | c.-27G>T | 5'UTR (SNP) | VAF 46/244 reads (19%) | catalogued as COSV100099927; called by muse, mutect2, varscan2
- TLL1 | c.*42G>T | 3'UTR (SNP) | VAF 32/150 reads (21%) | called by muse, mutect2, varscan2
- TRIML2 | c.746-846C>A | Intron (SNP) | VAF 22/127 reads (17%) | catalogued as rs529071248; called by muse, mutect2, varscan2
- UBE2DNL | n.531G>T | RNA (SNP) | VAF 29/136 reads (21%) | called by muse, mutect2, varscan2
- VSIG4 | c.962+29G>C | Intron (SNP) | VAF 13/76 reads (17%) | called by muse, mutect2, varscan2
- ZNF503 | c.-76C>T | 5'UTR (SNP) | VAF 20/100 reads (20%) | called by muse, mutect2, varscan2
- ZNF503 | c.-77G>T | 5'UTR (SNP) | VAF 20/98 reads (20%) | called by muse, mutect2, varscan2
- ZNF773 | chr19:57513049 C>A | 3'Flank (SNP) | VAF 11/121 reads (9%) | called by muse, mutect2
